MMRF case MMRF_1891 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/29d5affc-89af-4c04-904e-b160dea59e10

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.3 years (23,845 days); ISS stage: II; Days to last known disease status: 1,037 days (2.8 years); Days to last follow up: 1,037 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 103 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 204 days; Days to treatment end: 599 days (1.6 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 645 days (1.8 years); Days to treatment end: 1,037 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,058 days (2.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -42 (ECOG 1): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 318 mg/dL; Immunoglobulin G 46.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.199 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 30 g/L; Total Protein 9.5 g/dL; Glucose 5.5 mmol/L.
- Day 43 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 40.9 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.194 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 137 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 9 g/L; Immunoglobulin A 0.586 g/L; Immunoglobulin M 0.229 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 3.74 mmol/L.
- Day 204 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.5 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 0.591 g/L; Immunoglobulin M 0.964 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.24 mmol/L.
- Day 394 (ECOG 0): Hemoglobin 8.31 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 599 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.9 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.45 µg/mL; Lactate Dehydrogenase 2.1 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 687 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.9 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 771 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.6 mg/dL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 6.11 mmol/L.
- Day 855 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.8 mg/dL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 918 (ECOG 0): M Protein 1 g/dL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 4.84 mmol/L.
- Day 1,037 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 148 mg/dL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -42: Weight: 110 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1891_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -42 days.
- Sample MMRF_1891_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -42 days.
